Somatic mutation profile of tumor specimen TCGA-XK-AAK1-01A (aliquot TCGA-XK-AAK1-01A-11D-A41K-08) from TCGA case TCGA-XK-AAK1, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 62.9 years (22,965 days).
Specimen TCGA-XK-AAK1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33dc73e0-5afa-490c-b686-774d7d820d36.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XK-AAK1-10A (Blood Derived Normal), aliquot TCGA-XK-AAK1-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dff7f7c3-bc0d-4daf-9457-47c47f2a99c3

The open-access MAF lists 38 somatic variants for this specimen: 28 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 9, Nonsense Mutation 2, In Frame Del 1, In Frame Ins 1, Splice Site 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRE5 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.852); catalogued as rs367579729; called by muse, mutect2, varscan2
- AHRR | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs769138293, COSV57082347; called by muse, mutect2, varscan2
- AMBRA1 | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 91/149 reads (61%) | catalogued as COSV54049679; called by muse, mutect2, varscan2
- C10orf71 | c.661T>A p.S221T | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.018); catalogued as COSV100109779, COSV100110607; called by muse, mutect2, varscan2
- GPLD1 | c.822-1G>A p.X274_splice | Splice Site (SNP) | VAF 31/71 reads (44%) | catalogued as COSV100015563; called by muse, mutect2, varscan2
- H2AC8 | c.207C>G p.N69K | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99773371; called by muse, mutect2, varscan2
- KDM6A | c.3716G>A p.W1239* | Nonsense Mutation (SNP) | VAF 14/20 reads (70%) | catalogued as COSV100938550; called by muse, mutect2, varscan2
- KIRREL1 | c.698C>T p.T233M | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs763921449, COSV63286926, COSV63290072; called by muse, mutect2, varscan2
- KLRF1 | c.594C>A p.F198L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV99684533; called by muse, varscan2
- LDLR | c.1382G>A p.G461D | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99370284; called by muse, mutect2, varscan2
- LRRTM1 | c.808T>C p.Y270H | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0.018); catalogued as COSV99703070; called by muse, mutect2, varscan2
- MMACHC | c.368T>G p.V123G | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99423715; called by muse, mutect2, varscan2
- MMP9 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 113/257 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as rs1386256475, COSV63434153; called by muse, mutect2, varscan2
- MMP9 | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.498); catalogued as rs1179114145, COSV63433987; called by muse, mutect2, varscan2
- MUC16 | c.11788G>A p.E3930K | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.765); catalogued as rs1343652883, COSV101200255, COSV67505824; called by muse, mutect2, varscan2
- OR2M2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 108/267 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as rs142698993; called by muse, mutect2, varscan2
- PCDH7 | c.1437C>A p.D479E | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.63); PolyPhen benign (0.019); catalogued as COSV100688612; called by muse, mutect2, varscan2
- PIK3CG | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs757016725, COSV63247823; called by muse, mutect2, varscan2
- RNF186 | c.356G>T p.C119F | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.66); catalogued as COSV100909119; called by muse, mutect2, varscan2
- RUVBL1 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.115); catalogued as rs748047032, COSV100494259; called by muse, mutect2, varscan2
- RYR1 | c.12118G>A p.A4040T | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as rs374441925; called by muse, mutect2, varscan2
- SLC9A5 | c.893C>T p.S298L | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs1212004305, COSV100237544; called by muse, mutect2, varscan2
- THSD7A | c.3352T>G p.C1118G | Missense Mutation (SNP) | VAF 96/224 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs769874808, COSV101448877; called by muse, mutect2, varscan2
- TSHZ1 | c.320C>T p.S107L (on ENST00000580243 / NM_001308210.2; = p.S62L on NM_005786.6) | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs745502104, COSV59008218; called by muse, mutect2, varscan2
- WDR13 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99489604; called by muse, mutect2, varscan2
- H2BC7 | c.21del p.A8Lfs*12 | Frame Shift Del (DEL) | VAF 25/89 reads (28%) | called by mutect2, pindel, varscan2
- PRG4 | c.1741_1743del p.P581del | In Frame Del (DEL) | VAF 10/50 reads (20%) | called by mutect2, pindel, varscan2
- SSB | c.121_126dup p.K41_L42dup | In Frame Ins (INS) | VAF 14/31 reads (45%) | called by mutect2, pindel, varscan2
- ABHD12 | c.531C>T p.N177= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as rs756552729, COSV100194856; called by mutect2, varscan2
- NBAS | c.6369C>T p.D2123= | Silent (SNP) | VAF 37/88 reads (42%) | catalogued as COSV99871437; called by muse, mutect2, varscan2
- OR2B11 | c.603C>T p.T201= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV100276578; called by muse, mutect2, varscan2
- RAG2 | c.369C>A p.R123= | Silent (SNP) | VAF 40/129 reads (31%) | catalogued as COSV100271486; called by muse, mutect2, varscan2
- SH2D3C | c.867C>T p.S289= (on ENST00000314830 / NM_170600.3; = p.S132= on NM_005489.4) | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as COSV100137440; called by muse, varscan2
- SPATA13 | c.1161G>A p.P387= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as rs748574948, COSV57982209; called by muse, mutect2, varscan2
- TBX18 | c.723C>T p.S241= | Silent (SNP) | VAF 22/35 reads (63%) | catalogued as COSV100858573; called by muse, mutect2, varscan2
- UBASH3A | c.330C>T p.H110= | Silent (SNP) | VAF 39/95 reads (41%) | catalogued as rs192044505; called by muse, mutect2, varscan2
- UHRF1BP1L | c.471A>G p.A157= | Silent (SNP) | VAF 32/88 reads (36%) | catalogued as COSV99692090; called by muse, mutect2, varscan2
- DNAJA4 | c.132+1360C>T | Intron (SNP) | VAF 19/36 reads (53%) | catalogued as rs541929187, COSV100655244; called by muse, mutect2, varscan2
